Gene-level copy-number profile of tumor specimen MP2PRT-PAPIZN-TMP1-A from MP2PRT case MP2PRT-PAPIZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,328 days).
Specimen MP2PRT-PAPIZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e23d5269-6ecc-4ba0-b8cd-887185de08c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPIZN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/f67b8403-c309-455a-991d-464c9fbb81a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 619; copy number 1: 2,901; copy number 2: 54,756; copy number 3: 126; copy number 4: 20; copy number 6: 60; copy number 7: 108; copy number 9: 5; copy number 10: 82; copy number 12: 161; copy number 13: 57.

Homozygous deletions (total copy number 0; autosomes only): 619 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 37 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:89,989,987–90,011,184, 4 genes: IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22.
- chr2:118,088,452–119,525,301, 15 genes: INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1.
- chr2:173,871,653–173,965,702, 2 genes: RPL5P7, SP3.
- chr4:148,078,762–148,444,698, 2 genes: NR3C2, AC069272.1.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–1): TRGV5P, TRGV5.
- chr7:142,308,542–142,802,748, 74 genes (broad region; genes not listed).
- chr9:21,966,929–22,455,740, 10 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr12:109,553,715–111,451,623, 54 genes: MMAB, RNU4-32P, MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1, TCHP, GIT2, AC084876.1, AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2, IFT81, ATP2A2, RN7SL769P, ANAPC7, AC144548.1, HMGA1P3, ARPC3, GPN3, RPL31P49, FAM216A, VPS29, AC002350.1, AC002350.2, RAD9B, PPTC7, TCTN1, RN7SL387P, HVCN1, PPP1CC, AC144522.1, AC002375.1, RPL29P25, CCDC63, MYL2, LINC01405, AC002351.1, CUX2, MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3.
- chr13:49,247,925–52,159,861, 73 genes (broad region; genes not listed).
- chr14:105,672,308–106,538,344, 125 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,593,347, 3 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52, IGHV3-53.
- chr14:106,675,017–106,762,588, 11 genes (within-gene range 0–2): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D.
- chr15:25,848,747–25,848,825, 1 gene (within-gene range 0–2): MIR4715.
- chr20:3,384,229–3,384,440, 1 gene (within-gene range 0–2): U3.
- chr21:42,653,621–46,691,226, 165 genes (broad region; genes not listed).
- chr22:22,036,344–22,215,270, 20 genes (within-gene range 0–2): AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 473 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:14,819,699–14,918,552, 2 genes, copy number 6 (within-gene range 3–6): LINC02246, RBMX2P1.
- chr21:15,694,300–15,696,581, 1 gene, copy number 6: RAD23BP3.
- chr21:17,431,547–42,651,244, 470 genes, copy number 6–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
